BEATAML1.0 case 2462 — Functional Genomic Landscape of Acute Myeloid Leukemia (BEATAML1.0-COHORT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/ac6b2eb1-888d-4c29-805e-8338ddcaae99

Demographics
Sex at birth: male; Vital status: Dead.

Diagnoses (1)
1. Acute myeloid leukemia with myelodysplasia-related changes: ICD-O-3 morphology code: 9895/3; Tissue or organ of origin: Bone marrow; Age at diagnosis: 58.5 years (21,363 days); Progression or recurrence: no; ELN risk classification: Adverse.

Biospecimens (1 sample)
- Sample BA2967D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
